Surgical pathology report (de-identified scan), TCGA case TCGA-FG-6689, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-6689-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

SURGICAL PATHOLOGY REPORT

Addendum Present

Name:

Accession #:

Date of Procedure:

Date Received:

Submitting Physician:

Med. Rec #:

Location:

Race:

DOB/Sex:

FINAL DIAGNOSIS

A., B. RIGHT FRONTAL LOBE OF BRAIN, TUMOR, BIOPSY REMOVAL:
-- GEMISTOCYTIC ASTROCYTOMA, SEE NOTE.

Note: Mitotic figures are inconspicuous, and Ki-67 labeling index is low. GFAP and vimentin immunostains demonstrate a spectrum of morphologies ranging from mini-gemistocytes typically seen in oligodendroglial tumors to a predominant population of large gemistocytic astrocytic tumor cells. Although gemistocytic astrocytomas tend to behave in an aggressive fashion, they are considered Grade II tumors by the [REDACTED]. An addendum will be issued pending analysis for deletions in chromosomes 1 and 19.

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's). ASR's have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by the Department of Pathology at [REDACTED]. The assays were performed with appropriate positive and negative controls.

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A. Touch imprint and Microscopic: Glioma most consistent with oligodendrocytoma. [REDACTED]

Addendum/Procedures:

Addendum

Date Ordered:

Date Complete:

Date Reported:

Status: Signed Out

Addendum Diagnosis

{Not Entered}

Addendum Comment

Date Ordered:

Date Completed:

Specimen Source:

Paraffin Block No.:

BRAIN TUMOR

A2

TUMOR TISSUE ASSESSMENT

RESULTS

Chromosome 1p: Intact, aneusomic

[page 2 of 3]
Chromosome 19q: Intact, eusomic

Quantitative FISH results

1p36:3.9
1q25:3.5
1p36/1q25 ratio: 1.1

19q13:2.7
19q13: 2.9
19q13/19p13 ratio: 0.9

INTERPRETATION

1p intact: A majority of nuclei showed similar numbers of 1p36 and 1q25 signals. There is no evidence of allelic loss on the short arm of chromosome 1 (1p).

19q intact: A majority of nuclei showed similar numbers of 19q13 and 19p13 signals. There is no evidence of allelic loss of 19q.

Allelic loss at one locus does not necessarily predict the presence of alterations at other loci on the same chromosome, i.e. FISH may not detect partial allelic loss. FISH may not detect allelic losses if there is loss of one allele and replication on the allele.

Comment:

Several days after unstained slides from block A2 were received, additional unstained slides from block B1 were received. This was discussed with [REDACTED] on 2011. The unstained slides from block B1 will not be stained and will be returned.

Allelic loss on chromosome 1p has been shown to correlate with chemoresponsiveness and long progression-free survival in some gliomas. This correlation is stronger when there is concomitant allelic loss on 19q. An association of chemoresponsiveness and/or long progression-free survival with allelic loss on 19q in the absence of loss on 1p has not been established. In patients with 1p/19q loss,

Method:

The integrity of the short arm of chromosome 1 (1p) and long arm of chromosome 19 (19q) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using locus-specific probes target (1p36, 19q13) and reference probes (1q25, 19p13) (Abbott Molecular/Vysis, Des Plaines, IL). The analysis was performed on areas of glial neoplasm and only atypical nuclei with two or more reference probe signals were counted. Reported quantitative data represents an average of 40 nuclei. Loss is defined as a ratio of less than or equal to 0.7. Aneuploidy is defined as a mean of greater than or equal to 3.0 for the reference probe signals (1q25, 19p13).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

NOTE: One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASRs). ASRs have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by the [REDACTED] A copy of their report is on file in the Department of Anatomic Pathology of [REDACTED]

Electronically Signed Out By [REDACTED]

Clinical History:

'Right frontal brain tumor

Specimens Submitted As:

A:RIGHT FRONTAL TUMOR

[page 3 of 3]
B:BRAIN TUMOR

Gross Description:

A. Received fresh for intraoperative consultation, labeled with the patient's name and hospital number, is a 3 x 1.5 x 0.5 cm multiple tan white friable pieces of soft tissue. A portion of the specimen is submitted for frozen section. The specimen is submitted entirely in 2 cassettes.

B: Received in formalin, labeled with the patient's name and number, are 4 irregular, opaque white to tan-brown, soft, cerebriform tissue fragments ranging from 2.0 x 1.7 x 1.4 cm to 10.0 x 6.0 x 4.5 cm. Representative sections are submitted in 6 cassettes.

Summary of cassettes

A1FS

A2 remainder of specimen

Source: NCI Genomic Data Commons file 5ab30fbb-78ed-48ba-b21e-e1cd3cf38c64 (TCGA-FG-6689.CC32EE60-C475-48DD-ACD3-7E9C817507BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).